Somatic mutation profile of tumor specimen TCGA-W5-AA39-01A (aliquot TCGA-W5-AA39-01A-11D-A417-09) from TCGA case TCGA-W5-AA39, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G4; Age at diagnosis: 81.0 years (29,594 days).
Specimen TCGA-W5-AA39-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de596727-49a8-4fe9-b963-cfb0443c5bf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA39-10A (Blood Derived Normal), aliquot TCGA-W5-AA39-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca5bad7a-21bc-4187-a040-35efdf4a2b21

The open-access MAF lists 771 somatic variants for this specimen: 584 protein-altering or splice-affecting, 161 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 500, Silent 161, Frame Shift Del 28, Nonsense Mutation 20, Splice Site 12, Intron 12, RNA 9, Splice Region 8, In Frame Del 8, Frame Shift Ins 3, 5'Flank 3, In Frame Ins 2.

Variants (750 of 771; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.4031C>T p.S1344L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58615689; called by muse, mutect2, varscan2
- PTEN | c.959del p.L320* | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | hotspot (GDC flag); catalogued as rs1114167682; ClinVar: pathogenic; called by mutect2, pindel*, varscan2
- ACSM2B | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100313028; called by muse, mutect2, varscan2
- ADAM30 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.005); catalogued as COSV65560311; called by muse, mutect2, varscan2
- AFDN | c.3587A>C p.K1196T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); catalogued as COSV60041815; called by muse, mutect2, varscan2
- ANKMY1 | c.1975A>G p.R659G | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777092936; called by muse, mutect2, varscan2
- APBB3 | c.1144C>G p.R382G (on ENST00000357560 / NM_133173.2; = p.R389G on NM_006051.3) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.073); catalogued as COSV60051447; called by mutect2, varscan2
- ARID1B | c.3395A>G p.Y1132C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99266794; called by muse, mutect2, varscan2
- ARL8A | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756933001; called by muse, mutect2, varscan2
- ARMC4 | c.2501T>C p.I834T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs150213638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASCC2 | c.2101G>T p.G701W | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100316430; called by muse, mutect2, varscan2
- ASXL3 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV52472065; called by muse, mutect2, varscan2
- ATP6V1G1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as rs1475687820; called by muse, mutect2, varscan2
- ATP7B | c.1739A>T p.H580L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CD123063; called by muse, mutect2, varscan2
- B2M | c.152A>C p.H51P | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62564067; called by muse, mutect2, varscan2
- BCOR | c.4219T>C p.Y1407H (on ENST00000378444 / NM_001123385.2; = p.Y1373H on NM_017745.6) | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.646); catalogued as rs1389000842; called by muse, mutect2, varscan2
- BIRC3 | c.964T>G p.L322V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs373892386; called by muse, mutect2, varscan2
- BIRC6 | c.4679T>G p.L1560R | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70198175, COSV70200265; called by muse, mutect2, varscan2
- BMP4 | c.209G>C p.R70P | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55415586, COSV55417348; called by muse, mutect2, varscan2
- C1S | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1565625171; called by muse, mutect2, varscan2
- CALCR | c.740C>T p.A247V (on ENST00000649521 / NM_001164737.2; = p.A231V on NM_001742.4) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1297524627; called by muse, mutect2, varscan2
- CCDC74A | c.200T>C p.M67T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766157122; called by muse, varscan2
- CCDC9B | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs370895955; called by muse, mutect2, varscan2
- CDC20B | c.218T>G p.I73S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV99697020; called by muse, mutect2, varscan2
- CDC42BPB | c.4085C>T p.P1362L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV100775574; called by mutect2, varscan2
- CDH2 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52270225; called by muse, mutect2
- CDK12 | c.4058C>T p.T1353I (on ENST00000447079 / NM_016507.4; = p.T1344I on NM_015083.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.023); catalogued as rs1311838642, COSV70999438; called by muse, mutect2, varscan2
- CELF3 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs754604007, COSV99066717; called by muse, mutect2, varscan2
- CHAF1A | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as rs760936940; called by muse, mutect2, varscan2
- CHAMP1 | c.1323A>C p.K441N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63521735; called by muse, mutect2, varscan2
- COL24A1 | c.521G>C p.S174T | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100993600; called by muse, mutect2, varscan2
- CYC1 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV59645141; called by muse, mutect2, varscan2
- EDEM2 | c.676T>C p.W226R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1170857871; called by muse, mutect2
- EEF1A1 | c.121A>C p.K41Q | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); catalogued as COSV58549243; called by muse, varscan2
- EP300 | c.123C>G p.H41Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV54339514; called by muse, mutect2
- EP300 | c.7133G>A p.S2378N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV54337353; called by muse, mutect2, varscan2
- ERCC2 | c.2023G>T p.G675C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM950364, COSV67267039, COSV67269069; called by muse, mutect2, varscan2
- FAH | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1041287653; called by muse, mutect2, varscan2
- FBXO5 | c.399A>G p.I133M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV57670477; called by muse, varscan2
- FBXO6 | c.552A>C p.K184N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.64); PolyPhen benign (0.381); catalogued as rs757284886; called by muse, mutect2, varscan2
- FUZ | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs756077603; called by muse, mutect2, varscan2
- GMFG | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs150080208; called by muse, mutect2, varscan2
- GPR21 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV101016518; called by muse, mutect2, varscan2
- GRIK5 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs776996571, COSV99491423; called by muse, mutect2, varscan2
- GRIN2A | c.3523G>T p.E1175* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as rs867464241, COSV58027342, COSV58033157; called by muse, mutect2, varscan2
- HAUS4 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs551628708; called by muse, mutect2, varscan2
- HNRNPU | c.1655T>A p.V552D (on ENST00000283179; = p.V614D on NM_004501.3) | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs111577008; called by muse, mutect2, varscan2
- HOXA6 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs754446958; called by muse, mutect2, varscan2
- HSD17B14 | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.205); catalogued as rs1332639506; called by muse, mutect2, varscan2
- IL12B | c.367C>G p.P123A | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs780376200; called by muse, mutect2, varscan2
- IL33 | c.553A>C p.T185P | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV67342720; called by muse, mutect2, varscan2
- INHBA | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV54219836; called by muse, mutect2, varscan2
- INTS2 | c.2548C>A p.Q850K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.879); catalogued as COSV52156241; called by muse, mutect2, varscan2
- IRF6 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as CM092320; called by muse, mutect2, varscan2
- IRS1 | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs577419348; called by muse, mutect2, varscan2
- ISX | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100434063; called by muse, mutect2, varscan2
- ITGB4 | c.4691A>G p.Y1564C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52321985; called by muse, mutect2, varscan2
- ITPR3 | c.1059C>G p.C353W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV65414113; called by muse, mutect2, varscan2
- KCNF1 | c.1435del p.L479Sfs*2 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs972503924; called by mutect2, pindel, varscan2
- LAMB3 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as rs145170416; called by muse, mutect2, varscan2
- LEO1 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs367614131, COSV55177440; called by muse, mutect2, varscan2
- MAP3K2 | c.385A>C p.N129H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as COSV100789332; called by muse, mutect2, varscan2
- MARCHF6 | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 87/113 reads (77%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV56881452; called by muse, mutect2, varscan2
- MCOLN1 | c.437G>C p.R146P | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs147878118; called by muse, mutect2, varscan2
- MRPL2 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); catalogued as rs1234546914; called by muse, mutect2, varscan2
- MRPL44 | c.813T>G p.F271L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); catalogued as COSV51313779; called by muse, mutect2, varscan2
- MSRB2 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.127); catalogued as COSV64737365; called by muse, mutect2, varscan2
- MTUS1 | c.3257A>G p.D1086G (on ENST00000262102 / NM_001363061.1; = p.D252G on NM_020749.4) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as rs570318137; called by muse, mutect2, varscan2
- MYOM1 | c.3771A>C p.K1257N | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs920532350; called by muse, mutect2, varscan2
- NDN | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as rs746305919; called by muse, mutect2, varscan2
- NOM1 | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51979787; called by muse, mutect2, varscan2
- NOXO1 | c.307T>C p.Y103H (on ENST00000397280 / NM_172168.3; = p.Y97H on NM_144603.4) | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036317931; called by muse, mutect2, varscan2
- NPBWR2 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.847); catalogued as rs139565347; called by muse, mutect2, varscan2
- NRXN3 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750343246, COSV59751358; called by muse, mutect2, varscan2
- NXPH4 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61075548; called by muse, mutect2, varscan2
- ODF2 | c.1848A>C p.Q616H (on ENST00000434106 / NM_153433.2; = p.Q592H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV63547945; called by muse, varscan2
- ODF2 | c.1868A>C p.K623T (on ENST00000434106 / NM_153433.2; = p.K599T on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV63546304; called by muse, varscan2
- OR4N2 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV60054268; called by muse, mutect2, varscan2
- OR4Q3 | c.822C>G p.F274L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as COSV59178679; called by muse, mutect2, varscan2
- OR6V1 | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs1183116683; called by muse, mutect2, varscan2
- PAOX | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs752967870; called by muse, mutect2, varscan2
- PAPPA2 | c.5347C>G p.R1783G | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62791699; called by muse, mutect2, varscan2
- PAX8 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs777910954; called by muse, mutect2, varscan2
- PCARE | c.1847A>T p.Q616L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419165457; called by muse, mutect2, varscan2
- PCDHB7 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.005); catalogued as COSV99175175, COSV99177408; called by muse, mutect2, varscan2
- PCDHGA3 | c.731A>T p.Q244L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as rs1418296616, COSV54008583; called by muse, mutect2, varscan2
- PCDHGA6 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54007546; called by muse, mutect2, varscan2
- PCF11 | c.1768A>C p.S590R | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV100019575, COSV53527525, COSV99036186; called by muse, varscan2
- PCF11 | c.1775A>C p.K592T | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53530399; called by muse, varscan2
- PCGF5 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.921); catalogued as rs747593585; called by muse, mutect2, varscan2
- PCSK4 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs750890730; called by muse, mutect2, varscan2
- PDE4DIP | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs782802168; called by muse, mutect2, varscan2
- PFKM | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.03); catalogued as rs1018589600; called by muse, mutect2, varscan2
- PIK3R1 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs1350040171; called by muse, mutect2, varscan2
- PIKFYVE | c.2353C>G p.R785G | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV52248691; called by muse, mutect2, varscan2
- PLA2G4D | c.1872G>T p.W624C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1240557118; called by muse, mutect2, varscan2
- PLXNA4 | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs756544431, COSV100322604; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1111A>G p.N371D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs1166741714; called by muse, mutect2, varscan2
- PRG4 | c.2833A>G p.T945A | Missense Mutation (SNP) | VAF 52/91 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1230713014; called by muse, mutect2, varscan2
- QPRT | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54879780; called by muse, mutect2, varscan2
- RABGAP1 | c.2246T>C p.L749S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101017090; called by muse, mutect2, varscan2
- RBM4 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100029725; called by muse, mutect2, varscan2
- RHAG | c.1137A>C p.T379= | Splice Region (SNP) | VAF 27/37 reads (73%) | catalogued as COSV57705317; called by muse, mutect2, varscan2
- RIT1 | c.101A>T p.K34M | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64166861; called by muse, mutect2, varscan2
- SAP30L | c.508A>T p.S170C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1561703467; called by muse, mutect2, varscan2
- SELENOH | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.089); catalogued as rs771399022; called by muse, mutect2, varscan2
- SELENOT | c.359G>A p.W120* | Nonsense Mutation (SNP) | VAF 52/92 reads (57%) | catalogued as rs1418466639; called by muse, mutect2, varscan2
- SF3A3 | c.825C>G p.G275= | Splice Region (SNP) | VAF 25/57 reads (44%) | catalogued as COSV65955695; called by muse, mutect2, varscan2
- SF3B2 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as rs777083462; called by muse, mutect2, varscan2
- SLC17A3 | c.759+1G>A p.X253_splice | Splice Site (SNP) | VAF 23/39 reads (59%) | catalogued as rs773136308, COSV57760036; called by muse, mutect2, varscan2
- SLX4 | c.624G>T p.L208F | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1384609139; called by muse, mutect2, varscan2
- SMG1 | c.4661A>C p.N1554T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV101246724; called by muse, mutect2, varscan2
- SPTBN5 | c.3863A>G p.Q1288R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV58019833; called by muse, mutect2, varscan2
- STK32C | c.687T>G p.H229Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53838236; called by muse, mutect2
- SUSD6 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs368679025; called by muse, mutect2, varscan2
- TAF1D | c.745T>G p.L249V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as rs554467119; called by muse, mutect2, varscan2
- TAS1R2 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs755734470, COSV64744546; called by muse, mutect2, varscan2
- TAS2R9 | c.286A>C p.S96R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53688510; called by muse, varscan2
- TCP11L1 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs747040679, COSV57514548; called by muse, mutect2, varscan2
- TIMMDC1 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1560044126; called by muse, mutect2, varscan2
- TMTC4 | c.49C>T p.L17F (on ENST00000376234 / NM_001350577.2; = p.L36F on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV60893161; called by muse, mutect2, varscan2
- TTLL4 | c.859T>G p.L287V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs776330451; called by muse, mutect2, varscan2
- TTLL9 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV60590018; called by muse, mutect2, varscan2
- TTR | c.95T>G p.L32R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM993974; called by muse, mutect2, varscan2
- TYMP | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159212438; called by muse, mutect2, varscan2
- USPL1 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs770469215, COSV55000269; called by muse, mutect2, varscan2
- VNN1 | c.210+1G>A p.X70_splice | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as rs1232440487; called by muse, mutect2, varscan2
- ZCCHC8 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1419307468; called by muse, mutect2, varscan2
- ZNF134 | c.1088A>T p.Q363L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV104432797; called by muse, mutect2, varscan2
- ABCA13 | c.6146G>T p.S2049I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ABCC2 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ABI3 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ACADVL | c.591_604del p.Q197Hfs*51 | Frame Shift Del (DEL) | VAF 16/25 reads (64%) | called by mutect2, pindel, varscan2
- ACSL5 | c.507A>C p.E169D (on ENST00000354273; = p.E225D on NM_016234.3) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ACVR2A | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ADH6 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- AGFG1 | c.1280T>G p.F427C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AHNAK | c.2089A>T p.I697F | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- AIFM3 | c.1613G>T p.G538V | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALB | c.465_469del p.E155Dfs*9 | Frame Shift Del (DEL) | VAF 17/27 reads (63%) | called by mutect2, pindel, varscan2
- ANKFY1 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- ANKRD42 | c.548T>G p.L183R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AOX1 | c.1564T>C p.F522L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.45); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- AOX1 | c.3608A>T p.Q1203L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AP3S2 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- APBB3 | c.1293_1301delinsGGC p.R432_R434delinsA (on ENST00000357560 / NM_133173.2; = p.R439_R441delinsA on NM_006051.3) | In Frame Del (DEL) | VAF 22/35 reads (63%) | called by pindel, varscan2*
- APOB | c.4570T>C p.S1524P | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB2 | c.1700T>C p.L567P | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ASH1L | c.4771T>G p.F1591V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ASIC4 | c.878G>T p.W293L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ASPRV1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ATAD2B | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- ATAD2B | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- ATAD5 | c.4709T>A p.L1570* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- ATE1 | c.394A>G p.N132D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATF4 | c.104A>C p.D35A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- ATF6B | c.1072_1083del p.Q358_L361del | In Frame Del (DEL) | VAF 24/45 reads (53%) | called by mutect2, pindel, varscan2
- ATG2A | c.1006C>G p.Q336E | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ATP13A3 | c.2308A>T p.K770* | Nonsense Mutation (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- ATP13A3 | c.1115C>T p.T372I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP8B1 | c.2065A>T p.K689* | Nonsense Mutation (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- ATP9B | c.685A>T p.S229C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- BAIAP3 | c.1382_1407delinsG p.V461Gfs*70 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | called by pindel, varscan2*
- BAP1 | c.352T>G p.F118V | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- BCAN | c.1304A>G p.E435G | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL3 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BFSP1 | c.1321T>G p.F441V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BMP5 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- BMP6 | c.1415A>G p.Y472C | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- BRWD1 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BTBD8 | c.662+1G>T p.X221_splice | Splice Site (SNP) | VAF 19/26 reads (73%) | called by muse, mutect2, varscan2
- BTG3 | c.734A>C p.N245T | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- C11orf52 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C1QBP | c.266A>C p.E89A | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2CD2L | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- C3 | c.2588G>C p.R863T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C3orf56 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- C8orf33 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C9orf131 | c.40del p.D14Ifs*9 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- C9orf152 | c.495G>T p.M165I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1I | c.3584A>C p.E1195A | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- CALCB | c.149T>G p.L50R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CAPN1 | c.107A>C p.K36T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CARD11 | c.1046T>C p.L349P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CARMIL3 | c.2915G>A p.R972K | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CARNS1 | c.296A>G p.Q99R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASKIN1 | c.1452C>A p.F484L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CATSPERD | c.932_971del p.R311Qfs*4 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- CCDC170 | c.590T>G p.L197R | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CCDC83 | c.1109T>A p.V370E (on ENST00000342404 / NM_001286159.2; = p.V401E on NM_173556.5) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CDC14A | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- CDH13 | c.1990T>G p.S664A | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CDIPT | c.34A>G p.N12D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK2 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDR2L | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- CFHR5 | c.1442T>C p.F481S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- CHD1 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CHEK2 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CIDEB | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CLPX | c.1519_1531del p.H507Rfs*8 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- CNBD2 | c.322T>A p.C108S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- CNTN2 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- COG8 | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL20A1 | c.75A>C p.Q25H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- COL4A3 | c.757A>G p.N253D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- COL8A2 | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COPA | c.2771C>A p.S924Y | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPG2 | c.2278C>T p.H760Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CP | c.3034A>G p.S1012G | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPSF1 | c.4287C>T p.I1429= | Splice Region (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- CRAT | c.652C>A p.H218N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRYBG1 | c.5834C>T p.S1945F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYGA | c.333T>A p.C111* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- CTC1 | c.712A>T p.K238* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | called by muse, varscan2
- CTNND1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CTR9 | c.1760A>C p.K587T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- CTSB | c.769T>G p.S257A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTTNBP2NL | c.1549G>T p.G517W | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- CYBB | c.454T>G p.Y152D | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CYP20A1 | c.132T>G p.N44K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2E1 | c.38_61del p.W13_V20del | In Frame Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, varscan2
- CYP3A5 | c.1280_1282delinsT p.D427Vfs*41 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | called by pindel, varscan2*
- DAPK1 | c.757A>G p.R253G | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DAZAP1 | c.642_664del p.A215Pfs*204 | Frame Shift Del (DEL) | VAF 40/95 reads (42%) | called by mutect2, pindel, varscan2
- DCAF7 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- DCUN1D3 | c.516del p.A173Pfs*32 | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | called by mutect2, pindel, varscan2
- DDB2 | c.824T>G p.V275G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, varscan2
- DDX19A | c.1060A>C p.K354Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.78); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- DENND1A | c.582A>T p.E194D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DENND4C | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DGAT1 | c.613T>G p.F205V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by mutect2, varscan2
- DGKB | c.1649A>C p.D550A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DHH | c.1150T>C p.S384P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DHX40 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DICER1 | c.4030T>A p.S1344T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- DIP2C | c.3681_3703del p.T1229Gfs*48 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- DLL1 | c.413-2A>C p.X138_splice | Splice Site (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- DMAC2L | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DMXL1 | c.4489A>C p.S1497R | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- DNAH7 | c.2948T>C p.V983A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAI1 | c.1015T>C p.C339R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAJB6 | c.916A>G p.K306E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- DNAJC14 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAJC9 | c.239A>G p.E80G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DOCK10 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DRG2 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1602C>A p.F534L | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DXO | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- ECM2 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDEM2 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EGR4 | c.1487G>A p.R496H (on ENST00000545030; = p.R393H on NM_001965.4) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF3H | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EIF3H | c.43T>A p.S15T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF4G1 | c.1430A>T p.E477V (on ENST00000346169 / NM_198241.3; = p.E281V on NM_004953.5) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- EIF4G1 | c.1828A>C p.K610Q (on ENST00000346169 / NM_198241.3; = p.K414Q on NM_004953.5) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ELMOD1 | c.461_469dup p.R154_S156dup | In Frame Ins (INS) | VAF 16/48 reads (33%) | called by mutect2, varscan2
- ELP5 | c.122_131del p.L41Rfs*20 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- ERBB2 | c.2980T>G p.L994V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ESPN | c.2147T>G p.L716R | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EZR | c.134T>G p.F45C | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FARP2 | c.3067G>A p.G1023R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCHO2 | c.2244A>T p.G748= | Splice Region (SNP) | VAF 59/104 reads (57%) | called by muse, mutect2, varscan2
- FMN1 | c.3094A>C p.K1032Q (on ENST00000616417 / NM_001277313.2; = p.K809Q on NM_001103184.4) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FOXA2 | c.533A>C p.K178T (on ENST00000377115 / NM_153675.3; = p.K184T on NM_021784.5) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FRAS1 | c.5527A>G p.T1843A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FSCN1 | c.136T>C p.W46R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSHB | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FST | c.325A>G p.N109D | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FUS | c.1046C>G p.A349G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- GABRA4 | c.1610A>G p.Y537C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATAD1 | c.297A>T p.K99N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GC | c.607-9_617del p.X203_splice | Splice Site (DEL) | VAF 20/28 reads (71%) | called by mutect2, pindel, varscan2
- GIGYF2 | c.1497_1517del p.A500_A506del | In Frame Del (DEL) | VAF 17/36 reads (47%) | called by mutect2, pindel, varscan2
- GIMAP8 | c.1536_1537insA p.E513Rfs*10 | Frame Shift Ins (INS) | VAF 15/35 reads (43%) | called by mutect2, pindel*, varscan2*
- GIPC3 | c.787G>T p.G263C (on ENST00000644946; = p.A263S on NM_133261.3) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJA10 | c.15C>G p.N5K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GLG1 | c.1304C>A p.S435Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GOLGA6A | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by mutect2, varscan2
- GPATCH2 | c.1093T>G p.S365A | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR155 | c.145T>C p.C49R | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPX2 | c.515C>G p.T172S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUSB | c.1867_1883del p.R623Dfs*4 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | called by pindel, varscan2
- GZF1 | c.454A>G p.S152G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HAMP | c.142A>G p.S48G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HDAC6 | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- HK2 | c.512G>T p.W171L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPF | c.807_814del p.G270* | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- HNRNPM | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- HOOK1 | c.1657C>T p.H553Y | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HSPA12B | c.1148C>A p.A383D | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- HSPA8 | c.86T>G p.I29S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IARS1 | c.2993G>T p.R998L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- IDE | c.2750A>G p.N917S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- IKZF5 | c.43T>A p.F15I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IMP3 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- IMPA1 | c.338T>A p.V113E | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INTS10 | c.1679T>C p.I560T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- INTS7 | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IPO11 | c.444A>C p.L148F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- IPO13 | c.1698_1700dup p.A567dup | In Frame Ins (INS) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- IRF6 | c.368T>G p.I123S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGB4 | c.2859G>C p.E953D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ITIH1 | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ITPR2 | c.1697A>T p.D566V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- JCAD | c.3353C>G p.A1118G | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- JMJD1C | c.4484A>C p.K1495T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); called by muse, varscan2
- KBTBD4 | c.1518T>G p.I506M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- KCNAB2 | c.114T>G p.F38L | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH8 | c.851C>A p.S284Y | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNMA1 | c.549A>C p.L183F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KDM3A | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KIAA0319L | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KIAA1109 | c.5347_5362del p.P1783Ifs*35 | Frame Shift Del (DEL) | VAF 31/41 reads (76%) | called by mutect2, pindel, varscan2
- KIF14 | c.413T>G p.I138R | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIFBP | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- KMT2A | c.5243A>T p.K1748I | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KRT10 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT85 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- LAP3 | c.1082A>C p.D361A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LARP4 | c.1321T>C p.Y441H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- LIMD1 | c.838T>G p.L280V | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- LMBR1 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP1 | c.7199A>C p.K2400T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRP6 | c.4303T>A p.S1435T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRP6 | c.4097C>T p.P1366L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LRP6 | c.3571A>G p.I1191V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MACF1 | c.6927A>C p.Q2309H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- MAGED1 | c.2183C>A p.S728Y | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- MARCHF6 | c.1176G>A p.W392* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- MARVELD3 | c.939C>G p.I313M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- MAST1 | c.1376G>A p.C459Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAT1A | c.331_340del p.E111Pfs*24 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- MDN1 | c.4585A>C p.K1529Q | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED28 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MEIS2 | c.763T>G p.L255V (on ENST00000561208 / NM_170675.5; = p.L242V on NM_002399.3) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- MEX3C | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MGAT5B | c.1769G>T p.G590V (on ENST00000569840 / NM_001199172.2; = p.G588V on NM_144677.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MIDEAS | c.2579A>C p.Q860P | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- MLXIPL | c.821-16_829del p.X274_splice | Splice Site (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel
- MME | c.927A>C p.Q309H | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MMP9 | c.1902-7_1902-1del p.X634_splice | Splice Site (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel, varscan2
- MPDZ | c.2969_2989del p.C990_L997delinsF | In Frame Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- MPRIP | c.1208G>T p.W403L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MREG | c.518T>G p.L173R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MRPL11 | c.564A>C p.E188D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- MRPS16 | c.176A>C p.N59T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MUC5B | c.5732C>G p.T1911S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MUC5B | c.16651G>T p.D5551Y | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MYH9 | c.706-1G>T p.X236_splice | Splice Site (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- MYO18A | c.292A>C p.S98R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); called by muse, mutect2
- MYO7A | c.2078A>C p.K693T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- MYRIP | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NCOR1 | c.3781A>G p.R1261G | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NDEL1 | c.633A>C p.Q211H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NDUFA13 | c.322dup p.E108Gfs*? | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by pindel, varscan2
- NDUFA13 | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- NDUFB10 | c.132A>C p.E44D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- NDUFV1 | c.914G>C p.G305A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NEK6 | c.937A>G p.T313A | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NHLRC2 | c.1067T>C p.L356S | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NID1 | c.2414A>T p.E805V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, varscan2
- NOD2 | c.158T>G p.F53C | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOTCH4 | c.4343C>T p.P1448L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPLOC4 | c.1097A>C p.K366T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPR2 | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- NSD3 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- NUP98 | c.1310T>G p.F437C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- NUP98 | c.1259T>G p.F420C | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NUP98 | c.552_575del p.H186_K193del | In Frame Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel
- NVL | c.1421T>C p.L474P | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OGA | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGFOD1 | c.205T>A p.F69I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OR2D3 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- OR51S1 | c.119T>G p.I40S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5H14 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ORM1 | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.211); called by muse, varscan2
- OVCH1 | c.928T>G p.S310A | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- P4HA2 | c.1484del p.G495Vfs*32 | Frame Shift Del (DEL) | VAF 26/49 reads (53%) | called by mutect2, pindel, varscan2
- PAFAH1B2 | c.166T>G p.Y56D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- PAIP2 | c.258A>C p.Q86H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- PAIP2 | c.260T>G p.I87S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- PALLD | c.2500A>G p.I834V (on ENST00000505667 / NM_001166108.2; = p.I817V on NM_016081.4) | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PANX1 | c.266A>T p.Q89L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- PBRM1 | c.219_228del p.R74Sfs*18 | Frame Shift Del (DEL) | VAF 21/32 reads (66%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.1508T>C p.L503S | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PCDHGB1 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- PCF11 | c.1793A>C p.K598T | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, varscan2
- PCF11 | c.1816A>C p.S606R | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.08); called by muse, varscan2
- PDIA2 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- PDIK1L | c.580A>C p.S194R | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PEAK1 | c.3291_3310del p.M1098Cfs*10 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- PFKL | c.2297T>G p.L766R | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PGBD2 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHC3 | c.2467A>T p.S823C (on ENST00000494943 / NM_001308116.2; = p.S835C on NM_024947.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- PHF20L1 | c.2972T>C p.L991S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIK3CB | c.2070A>C p.Q690H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIK3R1 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIMREG | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PJA2 | c.1163A>C p.E388A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PLD1 | c.2115+1G>A p.X705_splice | Splice Site (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PLEKHG4 | c.2077T>G p.C693G | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHH3 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PLPP1 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA2 | c.5606A>T p.E1869V | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PLXNB2 | c.3404A>T p.E1135V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1584G>A p.W528* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- POLE | c.6397G>T p.V2133L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by mutect2, varscan2
- PPFIBP2 | c.1762A>C p.T588P | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R16A | c.520T>A p.Y174N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R3C | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP4R1 | c.1980T>G p.N660K (on ENST00000400556 / NM_001042388.3; = p.N643K on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PPP5C | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PRDM4 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRDX1 | c.29_38del p.H10Pfs*61 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- PRICKLE4 | c.57C>G p.N19K (on ENST00000359201; = p.N59K on NM_013397.6) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PRPF39 | c.1814A>C p.K605T | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PSD3 | c.1836A>C p.E612D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PSG5 | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PSMC1 | c.1088_1102del p.R363_I367del | In Frame Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- PTGER2 | c.123A>G p.I41M | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PTK2 | c.3097A>C p.N1033H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTK2B | c.2125_2141del p.A709Tfs*7 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel
- PUM2 | c.1465A>C p.S489R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PXMP4 | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PYGM | c.2213A>C p.E738A | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- RAB27B | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- RAB6A | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RABGEF1 | c.870A>C p.E290D (on ENST00000439720 / NM_001287061.2; = p.E277D on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- RAD17 | c.632T>A p.M211K (on ENST00000380774 / NM_133339.2; = p.M200K on NM_002873.1) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RAPGEF2 | c.2097T>G p.D699E | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RDX | c.808T>A p.Y270N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RET | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- RFC2 | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RFWD3 | c.1366T>G p.C456G | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RIMBP3 | c.3208G>C p.G1070R | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- RNF19B | c.1361A>C p.K454T | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- RNPS1 | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPRD1B | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.223); called by muse, mutect2
- RPS12 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RPS6KA3 | c.1612A>G p.R538G | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RPTN | c.509A>G p.H170R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- RPTN | c.507C>A p.H169Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); called by muse, mutect2
- RREB1 | c.5021T>G p.L1674R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- RTP4 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SAMD4A | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCFD1 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SCUBE2 | c.2810G>A p.G937E (on ENST00000649792 / NM_001367977.2; = p.G880E on NM_020974.3) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDR16C5 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- SENP2 | c.723-9_735del p.X241_splice | Splice Site (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- SENP5 | c.1718A>C p.D573A | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETX | c.2443T>G p.L815V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHBG | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SIPA1 | c.2509T>G p.S837A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SIPA1L3 | c.4909G>T p.G1637W | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SKIDA1 | c.1291A>G p.S431G | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- SLC10A7 | c.433T>G p.L145V | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- SLC12A1 | c.2680A>T p.K894* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | called by muse, varscan2
- SLC12A7 | c.260_282del p.N87Tfs*259 | Frame Shift Del (DEL) | VAF 20/34 reads (59%) | called by mutect2, pindel, varscan2
- SLC12A8 | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- SLC23A2 | c.1719A>C p.P573= | Splice Region (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- SLC25A16 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC27A5 | c.1988T>A p.F663Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC2A2 | c.1442T>G p.F481C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SLC3A2 | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC47A2 | c.1157T>G p.I386R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SNED1 | c.3262C>A p.H1088N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SNX14 | c.2072A>C p.Q691P (on ENST00000314673 / NM_001350535.1; = p.Q638P on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SNX14 | c.558T>G p.I186M (on ENST00000314673 / NM_001350535.1; = p.I142M on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- SNX30 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SNX5 | c.921T>G p.D307E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- SPAG4 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SPINK5 | c.2147A>T p.N716I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- SPRY4 | c.494G>T p.C165F (on ENST00000434127 / NM_001127496.3; = p.C188F on NM_030964.4) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SREK1IP1 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); called by muse, mutect2
- SRP54 | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ST6GAL1 | c.84A>C p.E28D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ST7L | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- STAG2 | c.2232A>C p.Q744H | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STARD5 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAT2 | c.1249A>T p.S417C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STK11IP | c.1933del p.A646Pfs*3 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, pindel*, varscan2
- STK39 | c.294A>C p.K98N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STX3 | c.172A>T p.K58* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- SUCO | c.2179C>G p.Q727E | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SUPT20H | c.2231C>T p.A744V (on ENST00000350612 / NM_001014286.3; = p.G710= on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUPT6H | c.1203A>C p.E401D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SVEP1 | c.4638T>A p.P1546= | Splice Region (SNP) | VAF 4/19 reads (21%) | called by mutect2, varscan2
- SYCP2 | c.1665+1G>A p.X555_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- SYDE2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SYNE2 | c.12335T>A p.L4112Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SYT1 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TAP1 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- TASOR2 | c.7055T>C p.I2352T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TBCCD1 | c.1593A>C p.E531D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TBX3 | c.1007C>A p.S336Y (on ENST00000257566 / NM_016569.4; = p.S316Y on NM_005996.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TENM1 | c.1124A>C p.Y375S | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.49); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TEX2 | c.1817_1824del p.Q606Lfs*2 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | called by mutect2, pindel, varscan2
- TGFBR2 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- THRAP3 | c.2031-8_2035del p.X677_splice | Splice Site (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel*, varscan2
- THSD7A | c.4546T>A p.S1516T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TIMM23 | c.560T>G p.L187R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TLE4 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- TMC4 | c.664A>T p.T222S (on ENST00000617472 / NM_001145303.3; = p.T216S on NM_144686.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TMCC1 | c.383C>A p.P128Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TMEM132D | c.1840A>T p.M614L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM150C | c.476A>G p.E159G | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMEM237 | c.176_199del p.R59_E66del (on ENST00000409883 / NM_001044385.3; = p.R51_E58del on NM_152388.4) | In Frame Del (DEL) | VAF 7/27 reads (26%) | called by mutect2, pindel
- TMEM39B | c.991T>G p.S331A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- TMPRSS11B | c.1090A>G p.N364D | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TNFRSF10D | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- TNK2 | c.682A>T p.T228S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TOP2A | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRAM1 | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAPPC9 | c.982A>T p.K328* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- TSPAN12 | c.61T>G p.F21V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TTC12 | c.1580C>A p.S527Y | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TTC39C | c.1069T>A p.Y357N (on ENST00000317571 / NM_001135993.2; = p.Y296N on NM_153211.4) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTL | c.524A>C p.N175T | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TVP23B | c.445T>A p.F149I | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TYK2 | c.3230A>C p.K1077T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- UBAP2 | c.2221T>G p.F741V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- UBFD1 | c.771A>C p.K257N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- UBN1 | c.1337A>G p.Q446R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- UBXN4 | c.413T>G p.F138C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2B15 | c.1044del p.G349Vfs*25 | Frame Shift Del (DEL) | VAF 37/61 reads (61%) | called by mutect2, pindel, varscan2
- UHMK1 | c.166T>G p.F56V | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- UNC5D | c.997A>T p.T333S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UNC93A | c.649A>G p.M217V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- UPP2 | c.486T>G p.D162E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UROD | c.88T>G p.Y30D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- USP34 | c.4226T>G p.M1409R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UTP14C | c.234A>C p.E78D | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- UTP20 | c.2333T>C p.M778T | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTRN | c.310A>T p.N104Y | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- VAMP5 | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- VNN1 | c.646T>G p.F216V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- VPS41 | c.357del p.H120Tfs*18 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- VWA8 | c.2225A>C p.N742T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WBP2 | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- WBP4 | c.28A>C p.K10Q | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDFY1 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- WDFY3 | c.5091T>G p.N1697K | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- WDR33 | c.3170A>C p.D1057A | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- WNK4 | c.2401_2402dup p.T802Pfs*134 | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- WNT3A | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WWP1 | c.1925A>G p.Q642R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- WWP2 | c.419T>A p.F140Y | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.84); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- XKR4 | c.511T>G p.F171V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, varscan2
- XKR4 | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- XPNPEP1 | c.799T>C p.S267P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- XYLB | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- YEATS2 | c.4267T>C p.*1423Rext*3 | Nonstop Mutation (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- ZBED4 | c.923A>T p.H308L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB11 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZBTB21 | c.1748G>C p.R583T | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBTB38 | c.1057A>T p.S353C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZC3H6 | c.1036A>G p.K346E | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZCCHC4 | c.1014A>C p.V338= | Splice Region (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- ZFAND2A | c.36A>C p.E12D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ZFAND2B | c.437T>G p.L146R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.137); called by muse, varscan2
- ZFAND6 | c.482T>G p.F161C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFC3H1 | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX3 | c.5008A>G p.S1670G | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFP2 | c.733A>C p.N245H | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZHX2 | c.1403A>C p.E468A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF136 | c.1083A>C p.E361D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ZNF184 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF281 | c.2275T>G p.L759V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF354A | c.159G>C p.L53= | Splice Region (SNP) | VAF 52/92 reads (57%) | called by muse, mutect2, varscan2
- ZNF354C | c.792A>C p.R264S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF410 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- ZNF500 | c.187G>C p.G63R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ZNF529 | c.1259A>C p.K420T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF583 | c.1112A>G p.Q371R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ZNF598 | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF606 | c.1029C>A p.N343K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF630 | c.950A>C p.K317T | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF699 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF721 | c.2546_2556del p.G849Vfs*11 (on ENST00000338977; = p.G861Vfs*11 on NM_133474.4) | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- ZNF74 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ZNF91 | c.1029T>G p.I343M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZNRF3 | c.653A>G p.D218G (on ENST00000544604 / NM_001206998.2; = p.D118G on NM_032173.3) | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZSWIM3 | c.1255T>G p.F419V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ABCA13 | c.12033G>A p.R4011= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- ABCB11 | c.2142T>G p.V714= | Silent (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- ABCC3 | c.1803G>C p.R601= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV53319342; called by muse, mutect2, varscan2
- ABCC3 | c.2767C>A p.R923= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs371874263; called by muse, mutect2, varscan2
- ACLY | c.1497C>T p.A499= | Silent (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- ACSM5 | c.1548A>C p.A516= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV59369650; called by muse, mutect2, varscan2
- ACVR1B | c.822C>A p.T274= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs1425060514, COSV57775950; called by muse, mutect2, varscan2
- ADCY3 | c.3180C>T p.H1060= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV53167765; called by muse, mutect2, varscan2
- ADGRG3 | c.1287C>T p.Y429= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs766924163, COSV59650408; called by muse, mutect2, varscan2
- ADGRV1 | c.13503A>G p.L4501= | Silent (SNP) | VAF 34/58 reads (59%) | called by muse, varscan2
- AFDN | c.1686T>C p.S562= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- AGO3 | c.2145A>C p.R715= | Silent (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- ALG11 | c.987G>A p.K329= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs921029114; called by muse, mutect2, varscan2
- ALOX12B | c.2100T>C p.S700= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- AMBP | c.108T>C p.N36= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs773084386; called by muse, mutect2, varscan2
- ANKFY1 | c.483A>C p.L161= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs766838085; called by muse, mutect2, varscan2
- APMAP | c.393C>T p.T131= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs777509276; called by muse, mutect2, varscan2
- ARMC6 | c.498T>C p.T166= (on ENST00000392336; = p.T141= on NM_033415.4) | Silent (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- ARSL | c.129G>C p.L43= | Silent (SNP) | VAF 15/16 reads (94%) | catalogued as COSV101140444; called by muse, mutect2, varscan2
- ATF5 | c.594C>T p.A198= | Silent (SNP) | VAF 24/34 reads (71%) | called by muse, mutect2, varscan2
- ATP8B3 | c.9T>A p.T3= | Silent (SNP) | VAF 11/15 reads (73%) | called by muse, mutect2, varscan2
- AXIN2 | c.2481G>T p.V827= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- B4GAT1 | c.402G>T p.L134= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- BIRC6 | c.3996T>C p.L1332= | Silent (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- BTNL9 | c.540C>G p.P180= | Silent (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- C10orf62 | c.453T>C p.A151= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- C19orf54 | c.741T>A p.A247= | Silent (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- C1orf174 | c.153A>C p.T51= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- C9orf85 | c.93G>A p.V31= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, varscan2
- CCT4 | c.1038T>A p.A346= | Silent (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- CDH23 | c.8937C>T p.L2979= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- CHRM2 | c.756C>T p.D252= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs531986911, COSV57765140, COSV57779856; called by muse, mutect2, varscan2
- CMTR1 | c.1695T>C p.T565= | Silent (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- CNTRL | c.6927A>T p.T2309= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- CNTROB | c.858T>G p.S286= | Silent (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- COL22A1 | c.1539G>A p.K513= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- COL28A1 | c.1812G>C p.G604= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV68082061; called by muse, mutect2, varscan2
- COL5A1 | c.1920C>T p.G640= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs781663334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CP | c.2541T>G p.T847= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as COSV52834465; called by muse, mutect2, varscan2
- CSMD1 | c.7749T>G p.A2583= (on ENST00000520002; = p.A2582= on NM_033225.6) | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- CSPG4 | c.6519G>A p.V2173= | Silent (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- CTIF | c.1641G>C p.L547= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- CTR9 | c.1392T>G p.L464= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100797357; called by muse, mutect2, varscan2
- CYP2F1 | c.1449T>A p.P483= | Silent (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- CYP4F22 | c.807C>T p.D269= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- DDB2 | c.780A>G p.T260= | Silent (SNP) | VAF 16/32 reads (50%) | called by muse, varscan2
- DDX11 | c.2715G>A p.L905= (on ENST00000545668 / NM_152438.2; = p.*857= on NM_004399.3) | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- DIP2C | c.3477C>A p.A1159= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- DLAT | c.1911G>A p.K637= | Silent (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- DNAH11 | c.2352G>A p.L784= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs1465890970, COSV100178131; called by muse, mutect2, varscan2
- DNAJB13 | c.624A>G p.P208= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- EIF4E2 | c.183T>G p.T61= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- ELAVL1 | c.84T>A p.P28= | Silent (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- ELL2 | c.918T>C p.P306= | Silent (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- EPB41L4A | c.753C>T p.H251= | Silent (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- ERN1 | c.858T>C p.V286= | Silent (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- EXOC1 | c.1755A>G p.K585= | Silent (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- FAAP100 | c.2046T>G p.T682= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- FBXO28 | c.1044A>G p.R348= | Silent (SNP) | VAF 41/59 reads (69%) | called by muse, mutect2, varscan2
- FBXO5 | c.435T>C p.S145= | Silent (SNP) | VAF 19/37 reads (51%) | called by muse, varscan2
- FER1L6 | c.4815T>G p.T1605= | Silent (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- FKBP8 | c.834G>A p.L278= (on ENST00000222308 / NM_001308373.2; = p.L279= on NM_012181.5) | Silent (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- FSTL4 | c.1146A>C p.S382= | Silent (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- GBA3 | c.6T>G p.A2= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1234227704; called by muse, mutect2, varscan2
- GCNT2 | c.930T>C p.V310= (on ENST00000379597 / NM_001374747.1; = p.V308= on NM_001491.3) | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- GDPD4 | c.1167C>T p.S389= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs199737312, COSV60022797; called by muse, mutect2, varscan2
- GUSB | c.1950T>C p.F650= | Silent (SNP) | VAF 29/58 reads (50%) | called by muse, varscan2
- HIRA | c.2316C>T p.L772= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs782078591; called by muse, mutect2, varscan2
- HIRA | c.1320T>C p.D440= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- HMGCS2 | c.636A>T p.G212= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- HOATZ | c.27T>A p.P9= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.15T>G p.L5= | Silent (SNP) | VAF 31/109 reads (28%) | called by muse, mutect2, varscan2
- IGF2R | c.6624A>C p.G2208= | Silent (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- IGHV3-48 | c.192G>A p.L64= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2
- IGSF9B | c.1071C>T p.V357= | Silent (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- INPP5F | c.3243T>A p.V1081= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs552783556; called by muse, mutect2, varscan2
- ISL2 | c.705C>A p.I235= | Silent (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- JMJD1C | c.4566A>T p.V1522= | Silent (SNP) | VAF 17/29 reads (59%) | called by muse, varscan2
- KRT85 | c.801C>A p.L267= | Silent (SNP) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- LIX1L | c.708T>G p.V236= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- LOXL2 | c.579A>C p.S193= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- LRRC8B | c.1305T>C p.N435= | Silent (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- LRRTM3 | c.12T>C p.N4= | Silent (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- MAGEH1 | c.564T>G p.S188= | Silent (SNP) | VAF 14/15 reads (93%) | catalogued as rs267606487; called by muse, mutect2, varscan2
- MCCC1 | c.1347A>T p.T449= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- MEF2D | c.378G>A p.G126= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as rs1235808983; called by muse, mutect2, varscan2
- MGAT5B | c.1770C>T p.G590= (on ENST00000569840 / NM_001199172.2; = p.G588= on NM_144677.3) | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- MICAL3 | c.1116T>G p.T372= | Silent (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- MPDZ | c.2790T>C p.T930= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs540572504; called by muse, mutect2, varscan2
- MRTO4 | c.360A>G p.T120= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- MYCBP2 | c.8352T>G p.P2784= (on ENST00000357337; = p.P2822= on NM_015057.5) | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- NUB1 | c.1515T>A p.P505= (on ENST00000568733 / NM_001243351.1; = p.P491= on NM_016118.4) | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs1177893414; called by muse, mutect2, varscan2
- NUDT22 | c.201C>G p.T67= | Silent (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- ODF2 | c.1842A>G p.Q614= (on ENST00000434106 / NM_153433.2; = p.Q590= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs769618911, COSV63545743, COSV63547401, COSV63548473; called by muse, varscan2
- PARP10 | c.366T>G p.P122= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV57298033; called by muse, mutect2
- PHF3 | c.3657A>C p.A1219= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- PIK3R4 | c.1176T>C p.C392= | Silent (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- PKD1L2 | c.594T>A p.R198= | Silent (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- PPP3CB | c.18G>T p.P6= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs1224083016; called by muse, mutect2, varscan2
- PRDM13 | c.2073A>G p.T691= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- PRELID3B | c.375A>G p.T125= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV54813876; called by muse, mutect2, varscan2
- PRKAB2 | c.165G>C p.G55= | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- PRMT7 | c.1164T>C p.T388= | Silent (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- PTDSS2 | c.810G>A p.L270= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs961635723; called by muse, mutect2, varscan2
- RAB11B | c.399T>C p.A133= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- RABGAP1 | c.1290C>G p.V430= | Silent (SNP) | VAF 39/108 reads (36%) | called by muse, mutect2, varscan2
- RAD50 | c.2139G>A p.K713= | Silent (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2
- RALGPS2 | c.9A>C p.L3= | Silent (SNP) | VAF 32/50 reads (64%) | catalogued as rs1321556307; called by muse, mutect2, varscan2
- RAPGEF3 | c.2700T>A p.A900= (on ENST00000389212; = p.A858= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- RAPSN | c.567G>C p.A189= | Silent (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- RB1CC1 | c.3736C>T p.L1246= | Silent (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- RECK | c.924T>G p.L308= | Silent (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- REL | c.1341G>C p.L447= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- RHPN1 | c.951A>G p.A317= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs1317890628; called by muse, mutect2, varscan2
- SDCCAG8 | c.2133T>A p.S711= | Silent (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- SDR16C5 | c.15G>T p.L5= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- SF3B1 | c.105T>G p.S35= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- SHANK2 | c.3849G>A p.E1283= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- SKP2 | c.1068T>G p.L356= | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- SLC16A10 | c.897A>C p.G299= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- SLC25A27 | c.417T>G p.V139= | Silent (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- SLC5A10 | c.859C>A p.R287= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs761410107; called by muse, mutect2, varscan2
- SMARCC2 | c.462G>A p.G154= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs1413994688; called by muse, mutect2, varscan2
- SMYD2 | c.729C>A p.L243= | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as rs934845329; called by muse, mutect2, varscan2
- SOAT1 | c.864T>C p.T288= | Silent (SNP) | VAF 50/67 reads (75%) | called by muse, varscan2
- SRD5A2 | c.219C>T p.L73= | Silent (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- SREBF1 | c.912T>C p.P304= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- SRGAP1 | c.2034T>C p.H678= | Silent (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- SRSF1 | c.600A>C p.P200= | Silent (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- STAG1 | c.3633T>C p.D1211= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- STAP2 | c.600G>A p.V200= | Silent (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- SYNCRIP | c.24A>G p.G8= | Silent (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- SYNJ2BP | c.303G>A p.Q101= | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- TAF2 | c.3303C>G p.P1101= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV65417458; called by muse, mutect2, varscan2
- TAS2R9 | c.300T>G p.T100= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, varscan2
- TBR1 | c.402C>T p.H134= | Silent (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- TDO2 | c.522T>G p.P174= | Silent (SNP) | VAF 23/29 reads (79%) | called by muse, mutect2, varscan2
- TMC4 | c.1365G>C p.G455= (on ENST00000617472 / NM_001145303.3; = p.G449= on NM_144686.4) | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- TMCO1 | c.315G>A p.K105= (on ENST00000612311 / NM_001256164.1; = p.K54= on NM_019026.6) | Silent (SNP) | VAF 56/88 reads (64%) | called by muse, mutect2, varscan2
- TMEM128 | c.336T>C p.Y112= (on ENST00000382753 / NM_001297552.2; = p.Y88= on NM_032927.3) | Silent (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- TMEM184A | c.999G>A p.K333= | Silent (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- TMEM245 | c.2346T>C p.F782= | Silent (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- TNRC6A | c.4743T>G p.T1581= | Silent (SNP) | VAF 31/39 reads (79%) | catalogued as rs781648480; called by muse, mutect2, varscan2
- TPP1 | c.1111A>C p.R371= | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- TTC39A | c.1668T>C p.L556= (on ENST00000447632 / NM_001297665.1; = p.L521= on NM_001080494.3) | Silent (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- TYRP1 | c.1413G>T p.R471= | Silent (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- UBE2F | c.342A>G p.E114= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- UBN2 | c.3096G>A p.S1032= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1012257828, COSV56032483; called by muse, mutect2, varscan2
- UBR2 | c.4446T>G p.A1482= | Silent (SNP) | VAF 29/47 reads (62%) | called by muse, mutect2, varscan2
- UPK3A | c.87T>G p.T29= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- USP12 | c.405A>C p.T135= | Silent (SNP) | VAF 45/116 reads (39%) | called by muse, mutect2, varscan2
- USP2 | c.339C>T p.F113= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- WDR61 | c.360T>C p.Y120= | Silent (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- ZBTB16 | c.1989A>T p.I663= | Silent (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- ZC3H15 | c.54A>G p.K18= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- ZNF513 | c.936C>T p.F312= | Silent (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.430A>C p.R144= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1332474504, COSV58672240; called by muse, mutect2, varscan2
- ZNF569 | c.621T>C p.I207= | Silent (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- ZNF69 | c.222T>C p.Y74= (on ENST00000429654 / NM_001364730.1; = p.Y60= on NM_021915.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as rs1337264337; called by muse, mutect2, varscan2
- ZNF770 | c.1558A>C p.R520= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- ZNF91 | c.1584A>G p.R528= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100323334; called by muse, mutect2, varscan2
- ANGPTL8 | chr19:11239618 del TAT | 5'UTR (DEL) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- ANKRD33 | chr12:51888186 T>C | 5'Flank (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- AP000769.5 | chr11:65499114 A>C | 5'Flank (SNP) | VAF 16/36 reads (44%) | catalogued as rs766966793; called by muse, mutect2, varscan2
- CDKL1 | c.367-695T>C | Intron (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- CREM | c.891-372G>C | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
21 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 21 other) are not listed here.
